Somatic mutation profile of tumor specimen ALCH-ADYK-TTP1-A (aliquot ALCH-ADYK-TTP1-A-1-0-D-A603-36) from ALCHEMIST case ALCH-ADYK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.1 years (24,134 days).
Specimen ALCH-ADYK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec118b47-7ddc-49b3-9f66-2020b205c7b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADYK-NB1-A (Blood Derived Normal), aliquot ALCH-ADYK-NB1-A-1-0-D-A603-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90c9f001-4765-4999-b9ef-b7da41868566

The open-access MAF lists 117 somatic variants for this specimen: 78 protein-altering or splice-affecting, 21 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 21, Intron 12, Nonsense Mutation 6, RNA 4, Frame Shift Ins 3, 5'Flank 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 136/460 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- STK11 | c.481A>T p.I161F | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as rs1131690938, CM134908, COSV58828738; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACSL4 | c.1757G>T p.G586V (on ENST00000340800 / NM_022977.2; = p.G545V on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 147/265 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61615494; called by muse, mutect2, varscan2
- AQP12B | c.407C>T p.A136V (on ENST00000621682; = p.A148V on NM_001102467.2) | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.133); catalogued as rs1322342792; called by muse, mutect2, varscan2
- CLOCK | c.711A>G p.I237M | Missense Mutation (SNP) | VAF 57/313 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs1480003388; called by muse, mutect2, varscan2
- COL5A1 | c.1796C>G p.P599R | Missense Mutation (SNP) | VAF 169/585 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.449); catalogued as COSV65665280, COSV65670286; called by muse, mutect2, varscan2
- CREBBP | c.395G>T p.S132I | Missense Mutation (SNP) | VAF 124/456 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.732); catalogued as COSV99269720; called by muse, mutect2, varscan2
- CUX2 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 48/227 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55647004; called by muse, varscan2
- CYP2C19 | c.778C>A p.P260T | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs556994963, COSV100990610; called by muse, mutect2, varscan2
- DNAI4 | c.5C>T p.T2M | Missense Mutation (SNP) | VAF 23/139 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.681); catalogued as rs1369509267; called by muse, varscan2
- GRXCR1 | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 79/289 reads (27%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.991); catalogued as COSV67674489; called by muse, mutect2, varscan2
- KIF2B | c.1219G>A p.G407R | Missense Mutation (SNP) | VAF 39/261 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758754788, COSV52130990; called by muse, mutect2, varscan2
- KLHL14 | c.1676G>T p.G559V | Missense Mutation (SNP) | VAF 16/466 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100839069; called by muse, mutect2
- LRP6 | c.2581A>T p.T861S | Missense Mutation (SNP) | VAF 33/269 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as rs747073423; called by muse, mutect2, varscan2
- MBD1 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 310/945 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.544); catalogued as COSV54003103, COSV54008217; called by muse, mutect2, varscan2
- MEGF10 | c.3167G>A p.R1056Q | Missense Mutation (SNP) | VAF 72/465 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.139); catalogued as rs1453250767, COSV57250130; called by muse, mutect2, varscan2
- MYL3 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 48/286 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.515); catalogued as COSV52768010; called by muse, mutect2, varscan2
- NR0B1 | c.362C>A p.P121Q | Missense Mutation (SNP) | VAF 93/202 reads (46%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); catalogued as COSV66764750; called by muse, mutect2, varscan2
- OR2M5 | c.385C>A p.P129T | Missense Mutation (SNP) | VAF 111/459 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV63546597; called by muse, mutect2, varscan2
- OR52N2 | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs746188141, COSV57676062, COSV57677371; called by muse, mutect2, varscan2
- OR5D14 | c.760C>A p.H254N | Missense Mutation (SNP) | VAF 54/228 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV59457985; called by muse, mutect2, varscan2
- PAPPA2 | c.5002G>T p.E1668* | Nonsense Mutation (SNP) | VAF 93/318 reads (29%) | catalogued as COSV62811897; called by muse, mutect2, varscan2
- PLXNA4 | c.1463C>A p.S488Y | Missense Mutation (SNP) | VAF 103/410 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100326362; called by muse, mutect2, varscan2
- POM121L12 | c.407C>A p.P136Q | Missense Mutation (SNP) | VAF 84/387 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101374974; called by muse, mutect2, varscan2
- PTPN12 | c.1831A>G p.R611G | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs947095687; called by muse, mutect2, varscan2
- SAFB2 | c.2239C>T p.R747C | Missense Mutation (SNP) | VAF 66/285 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772797669, COSV53044499; called by muse, mutect2, varscan2
- SERPINB2 | c.929C>A p.P310H | Missense Mutation (SNP) | VAF 26/338 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772506058, COSV55091246; called by muse, mutect2
- SHOX | c.140G>T p.R47L | Missense Mutation (SNP) | VAF 67/589 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.046); catalogued as COSV61862286; called by muse, mutect2, varscan2
- SLC18A2 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as rs756722746, COSV53688287; called by muse, varscan2
- STIM1 | c.1553A>T p.H518L | Missense Mutation (SNP) | VAF 118/563 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV56157317; called by muse, mutect2, varscan2
- TEC | c.1747C>T p.R583* | Nonsense Mutation (SNP) | VAF 21/255 reads (8%) | catalogued as COSV51912729; called by muse, mutect2
- WDFY4 | c.511C>A p.L171I | Missense Mutation (SNP) | VAF 66/314 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57434103; called by muse, mutect2, varscan2
- ZNF804A | c.1979C>A p.P660H | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.594); catalogued as COSV56447959; called by muse, mutect2, varscan2
- ADAM9 | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 187/635 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ADM | c.55_56dup p.D20Lfs*21 | Frame Shift Ins (INS) | VAF 62/701 reads (9%) | called by mutect2, pindel
- AL359922.1 | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 62/245 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- AL441992.2 | c.1231G>T p.D411Y | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ARFGEF3 | c.4257dup p.A1420Cfs*15 | Frame Shift Ins (INS) | VAF 106/411 reads (26%) | called by mutect2, pindel, varscan2
- ATM | c.4833dup p.E1612* | Frame Shift Ins (INS) | VAF 88/439 reads (20%) | called by mutect2, pindel, varscan2
- CASZ1 | c.766G>T p.A256S | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- CFAP54 | c.3395T>C p.V1132A | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- COL11A1 | c.4928C>A p.S1643Y | Missense Mutation (SNP) | VAF 53/341 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- CRLF2 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 44/375 reads (12%) | called by muse, mutect2, varscan2
- CSMD3 | c.6487G>A p.D2163N (on ENST00000297405 / NM_001363185.1; = p.D2059N on NM_052900.3) | Missense Mutation (SNP) | VAF 42/468 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DAB1 | c.1712G>C p.G571A (on ENST00000371231; = p.G538A on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ELK3 | c.613T>C p.S205P | Missense Mutation (SNP) | VAF 67/446 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EVX2 | c.586A>T p.T196S | Missense Mutation (SNP) | VAF 80/317 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- FAT4 | c.7730T>A p.M2577K | Missense Mutation (SNP) | VAF 54/336 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- FKTN | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 54/534 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.355); called by muse, mutect2
- GPR174 | c.256T>C p.F86L | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- IGHG3 | c.1034G>A p.S345N | Missense Mutation (SNP) | VAF 269/1046 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- KANK1 | c.1552G>C p.A518P | Missense Mutation (SNP) | VAF 111/365 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KAZALD1 | c.333C>G p.D111E | Missense Mutation (SNP) | VAF 119/410 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- LRRTM3 | c.1430A>T p.Q477L | Missense Mutation (SNP) | VAF 54/427 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MKI67 | c.5125G>A p.D1709N | Missense Mutation (SNP) | VAF 63/214 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- MYH13 | c.141T>A p.Y47* | Nonsense Mutation (SNP) | VAF 56/374 reads (15%) | called by muse, mutect2, varscan2
- MYO7B | c.5698C>A p.P1900T | Missense Mutation (SNP) | VAF 42/506 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OGA | c.2195G>A p.C732Y | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- OR14K1 | c.407G>C p.R136T | Missense Mutation (SNP) | VAF 75/272 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- OR6C65 | c.423G>T p.W141C | Missense Mutation (SNP) | VAF 59/273 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- PCDHB9 | c.2138T>A p.L713Q | Missense Mutation (SNP) | VAF 66/484 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PEG3 | c.1954G>T p.G652W | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PIK3C3 | c.1678C>T p.Q560* | Nonsense Mutation (SNP) | VAF 198/514 reads (39%) | called by mutect2, varscan2
- PLCB4 | c.3523G>A p.V1175I (on ENST00000278655 / NM_182797.3; = p.S1187N on NM_000933.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/447 reads (12%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- PSIP1 | c.512C>G p.S171C | Missense Mutation (SNP) | VAF 33/217 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- PSMA6 | c.205T>A p.L69I | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- RSBN1L | c.896A>C p.N299T | Missense Mutation (SNP) | VAF 64/247 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC17A6 | c.27G>T p.L9F | Missense Mutation (SNP) | VAF 26/257 reads (10%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SLC6A15 | c.1806G>T p.W602C | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPATA31D1 | c.2246C>A p.A749E | Missense Mutation (SNP) | VAF 165/649 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPTAN1 | c.3037C>T p.Q1013* | Nonsense Mutation (SNP) | VAF 167/670 reads (25%) | called by muse, varscan2
- TOR4A | c.559C>A p.P187T | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRIM48 | c.40C>A p.Q14K | Missense Mutation (SNP) | VAF 32/305 reads (10%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- TXNRD1 | c.980G>T p.C327F (on ENST00000525566 / NM_001093771.3; = p.C229F on NM_003330.4) | Missense Mutation (SNP) | VAF 61/362 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- UBASH3A | c.1759_1760del p.H588Rfs*38 | Frame Shift Del (DEL) | VAF 92/320 reads (29%) | called by mutect2, pindel, varscan2
- ZMAT4 | c.669G>T p.Q223H | Missense Mutation (SNP) | VAF 48/241 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ZNF423 | c.3441G>T p.M1147I (on ENST00000563137 / NM_001379286.1; = p.M1139I on NM_015069.4) | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2
- ZNF735 | c.739G>T p.G247C | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- ADGRL4 | c.1017A>T p.S339= | Silent (SNP) | VAF 40/328 reads (12%) | called by muse, mutect2, varscan2
- ADH6 | c.159G>T p.V53= | Silent (SNP) | VAF 32/141 reads (23%) | called by muse, mutect2, varscan2
- EXOSC3 | c.528A>T p.P176= | Silent (SNP) | VAF 76/283 reads (27%) | called by muse, mutect2, varscan2
- GCC1 | c.1326G>C p.L442= | Silent (SNP) | VAF 143/588 reads (24%) | called by muse, mutect2, varscan2
- GXYLT1 | c.781A>C p.R261= | Silent (SNP) | VAF 105/382 reads (27%) | called by muse, mutect2, varscan2
- MUC2 | c.1911C>A p.R637= | Silent (SNP) | VAF 41/219 reads (19%) | called by muse, mutect2, varscan2
- OR2AG1 | c.460C>T p.L154= | Silent (SNP) | VAF 80/306 reads (26%) | called by muse, mutect2, varscan2
- OR2T11 | c.540A>G p.A180= | Silent (SNP) | VAF 97/373 reads (26%) | called by muse, mutect2, varscan2
- OR51F1 | c.324C>A p.V108= | Silent (SNP) | VAF 29/191 reads (15%) | called by muse, mutect2
- PKD1 | c.3750C>G p.G1250= | Silent (SNP) | VAF 63/477 reads (13%) | called by muse, mutect2, varscan2
- PRDM13 | c.183G>T p.G61= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as COSV65030819; called by muse, mutect2, varscan2
- SERPINB13 | c.981C>A p.A327= | Silent (SNP) | VAF 24/258 reads (9%) | catalogued as COSV54027994; called by muse, mutect2
- SIGLEC1 | c.216C>T p.H72= | Silent (SNP) | VAF 65/225 reads (29%) | catalogued as rs199508541; called by muse, mutect2, varscan2
- SLC46A3 | c.1260G>T p.L420= | Silent (SNP) | VAF 40/246 reads (16%) | catalogued as COSV99906573; called by muse, mutect2, varscan2
- SNRNP70 | c.87A>T p.P29= | Silent (SNP) | VAF 70/287 reads (24%) | called by muse, mutect2, varscan2
- SNX20 | c.378G>A p.A126= | Silent (SNP) | VAF 31/238 reads (13%) | catalogued as COSV56058107; called by muse, mutect2, varscan2
- TF | c.543G>A p.A181= | Silent (SNP) | VAF 61/536 reads (11%) | catalogued as rs765159608; called by muse, mutect2, varscan2
- TMEM201 | c.1941C>T p.A647= | Silent (SNP) | VAF 34/222 reads (15%) | catalogued as rs1245573540; called by muse, mutect2, varscan2
- VTI1A | c.324G>A p.G108= | Silent (SNP) | VAF 54/222 reads (24%) | called by muse, varscan2
- ZFHX4 | c.7056C>G p.S2352= | Silent (SNP) | VAF 88/357 reads (25%) | catalogued as COSV50558591; called by muse, mutect2, varscan2
- ZNF846 | c.1587A>G p.A529= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs563251527; called by muse, varscan2
- AC100868.1 | c.152-2112T>C | Intron (SNP) | VAF 108/488 reads (22%) | called by muse, mutect2, varscan2
- AIPL1 | c.785-39G>T | Intron (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2, varscan2
- BBS1 | c.831-286A>G | Intron (SNP) | VAF 111/383 reads (29%) | called by muse, mutect2, varscan2
- C11orf40 | n.607C>T | RNA (SNP) | VAF 22/228 reads (10%) | catalogued as rs1366919368, COSV56890447; called by muse, mutect2, varscan2
- CYP3A7-CYP3A51P | chr7:99735098 A>G | 5'Flank (SNP) | VAF 175/820 reads (21%) | catalogued as rs1216053343; called by muse, mutect2, varscan2
- FGFR1 | c.936+52G>C | Intron (SNP) | VAF 20/173 reads (12%) | called by muse, mutect2, varscan2
- GULP1 | c.-172+4475A>G | Intron (SNP) | VAF 33/150 reads (22%) | catalogued as rs1222640101; called by muse, mutect2, varscan2
- MAPK9 | c.122+503G>T | Intron (SNP) | VAF 46/548 reads (8%) | catalogued as rs900140199; called by muse, mutect2
- MMP26 | c.-145+92881C>A | Intron (SNP) | VAF 60/247 reads (24%) | called by muse, mutect2, varscan2
- NPIPB14P | n.480A>T | RNA (SNP) | VAF 35/360 reads (10%) | called by muse, mutect2, varscan2
- OR7D1P | n.531del | RNA (DEL) | VAF 99/411 reads (24%) | called by mutect2, pindel, varscan2
- PKD1 | c.7065+10G>T | Intron (SNP) | VAF 19/173 reads (11%) | catalogued as rs539995198; called by muse, mutect2, varscan2
- PKD1 | c.7065+9C>A | Intron (SNP) | VAF 19/173 reads (11%) | called by muse, mutect2, varscan2
- PPP1R3B | chr8:9155058 G>T | 5'Flank (SNP) | VAF 42/313 reads (13%) | catalogued as rs1050412891; called by muse, mutect2, varscan2
- PRSS21 | c.91+26C>G | Intron (SNP) | VAF 27/94 reads (29%) | called by muse, mutect2, varscan2
- RBM14 | c.337+1455A>G | Intron (SNP) | VAF 32/412 reads (8%) | catalogued as rs755666389; called by muse, mutect2
- SKP1P2 | n.249C>T | RNA (SNP) | VAF 62/443 reads (14%) | catalogued as rs780024718; called by muse, mutect2, varscan2
- TPK1 | c.185+15159G>A | Intron (SNP) | VAF 17/407 reads (4%) | catalogued as rs1375349156; called by muse, mutect2
